Somatic mutation profile of tumor specimen MMRF_2567_1_BM_CD138pos (aliquot MMRF_2567_1_BM_CD138pos_T1_KHS5U_L12917) from MMRF case MMRF_2567, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,917 days).
Specimen MMRF_2567_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2124f431-2275-42b8-86b1-f9f60d65e879.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2567_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2567_1_PB_WBC_C3_KHS5U_L12918; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba93c5d5-79ea-4140-abe6-501fdb04680d

The open-access MAF lists 158 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 46, Silent 22, Intron 21, Nonsense Mutation 5, 5'UTR 4, RNA 4, 3'Flank 2, Frame Shift Del 2, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 59/169 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, mutect2, varscan2
- ADAMTS20 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867277411; called by muse, mutect2, varscan2
- ADCY9 | c.3604G>C p.V1202L | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53573880; called by muse, mutect2
- AFDN | c.4828C>T p.R1610W (on ENST00000447894 / NM_001366320.1; = p.R1608W on NM_001040000.3) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1291046499; called by muse, mutect2, varscan2
- ALG12 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 91/209 reads (44%) | PolyPhen probably damaging (0.956); catalogued as rs759024738, COSV58206420; called by muse, mutect2, varscan2
- CACNG8 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as rs1200260318; called by muse, mutect2, varscan2
- CNTN5 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 140/426 reads (33%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.125); catalogued as rs1240220761; called by muse, mutect2, varscan2
- GHR | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV50109745, COSV50136896; called by muse, mutect2, varscan2
- GRXCR1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 102/261 reads (39%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as rs750209285; called by muse, mutect2, varscan2
- H1-8 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1011934098; called by muse, mutect2, varscan2
- IGHV2-70 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368957766; called by muse, varscan2
- IGLV3-1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs372924773; called by muse, varscan2
- IGLV3-1 | c.281G>C p.S94T | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as rs375164349; called by muse, varscan2
- IGLV3-1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs368499668; called by muse, varscan2
- MUC16 | c.34768G>A p.G11590R | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV101200081, COSV67471102; called by muse, mutect2
- NKX2-6 | c.248T>C p.M83T | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.082); catalogued as rs772599709, COSV61493090; called by muse, varscan2
- NRAP | c.2396A>T p.E799V (on ENST00000359988 / NM_001322945.2; = p.E764V on NM_006175.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1219284325, COSV63491291; called by muse, mutect2, varscan2
- PMPCA | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as rs772027681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIP5K2 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs782715830; called by muse, mutect2, varscan2
- SF3B4 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.662); catalogued as rs1553765621; called by muse, mutect2, varscan2
- TENT5C | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 91/220 reads (41%) | catalogued as rs921184290, COSV65616704; called by muse, mutect2, varscan2
- THBS1 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs369659280; called by muse, mutect2, varscan2
- TRIM68 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs572500115; called by muse, mutect2, varscan2
- USP29 | c.1864C>A p.L622M | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV54140794, COSV54146518; called by muse, mutect2, varscan2
- ANLN | c.3047A>T p.Y1016F | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ASTE1 | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 124/375 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- B4GALNT2 | c.36C>G p.H12Q | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BAZ1B | c.3430A>T p.K1144* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2
- BSDC1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- C20orf144 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- C9orf131 | c.1796C>G p.A599G | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CDC73 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDK5RAP2 | c.4934C>A p.P1645H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CFAP54 | c.4278del p.F1426Lfs*28 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- DAB1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDX6 | c.1034del p.Q345Rfs*6 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- EML6 | c.4262C>T p.T1421I | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- FAM83F | c.1100C>A p.S367* | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- FBN3 | c.7088-1G>T p.X2363_splice | Splice Site (SNP) | VAF 92/425 reads (22%) | called by muse, mutect2, varscan2
- HAUS5 | c.1793A>C p.Q598P | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HCRTR2 | c.1328A>C p.N443T | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- HECTD4 | c.3122G>A p.R1041K | Missense Mutation (SNP) | VAF 140/399 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IDUA | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- IGHV1-69D | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IST1 | c.117G>C p.E39D (on ENST00000535424 / NM_001270976.1; = p.E26D on NM_014761.4) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- MMRN1 | c.1424A>T p.E475V | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PABPC3 | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PRLH | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPL4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SETD5 | c.2428C>T p.Q810* | Nonsense Mutation (SNP) | VAF 186/334 reads (56%) | called by muse, mutect2, varscan2
- SPINK13 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SQSTM1 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTC28 | c.3641C>T p.S1214F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- USP9X | c.6136C>T p.Q2046* | Nonsense Mutation (SNP) | VAF 79/96 reads (82%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZIM3 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF180 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZNF814 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ADCY1 | c.1629G>A p.S543= | Silent (SNP) | VAF 90/353 reads (25%) | catalogued as rs370138365; called by muse, varscan2
- APOL6 | c.723C>T p.S241= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs573758358, COSV68749533; called by muse, mutect2, varscan2
- AQP5 | c.180G>A p.L60= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs1187289790; called by muse, mutect2, varscan2
- ARMCX4 | c.207G>A p.L69= | Silent (SNP) | VAF 24/27 reads (89%) | called by muse, mutect2, varscan2
- C6orf15 | c.873T>G p.G291= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- CHST8 | c.849C>T p.F283= | Silent (SNP) | VAF 172/541 reads (32%) | catalogued as rs755960380; called by muse, mutect2, varscan2
- DDX43 | c.660T>C p.N220= | Silent (SNP) | VAF 48/175 reads (27%) | called by muse, mutect2, varscan2
- FAM160A2 | c.2259G>A p.L753= (on ENST00000449352 / NM_001098794.2; = p.L767= on NM_032127.4) | Silent (SNP) | VAF 75/303 reads (25%) | catalogued as rs1311143667; called by muse, mutect2, varscan2
- GSAP | c.861C>G p.T287= | Silent (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.156A>C p.G52= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as rs1232476476; called by muse, varscan2
- IGLV3-19 | c.12C>T p.T4= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1314607718; called by muse, mutect2, varscan2
- INTS13 | c.453A>G p.A151= | Silent (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- LCA5 | c.1221G>A p.K407= | Silent (SNP) | VAF 143/262 reads (55%) | called by muse, mutect2, varscan2
- LGR6 | c.2628G>A p.V876= (on ENST00000367278 / NM_001017403.1; = p.V824= on NM_021636.3) | Silent (SNP) | VAF 59/244 reads (24%) | catalogued as rs1450525261; called by muse, mutect2, varscan2
- LHB | c.384G>A p.L128= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV55485924; called by muse, mutect2, varscan2
- MALRD1 | c.2244T>A p.A748= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- MRPL4 | c.846C>T p.P282= | Silent (SNP) | VAF 62/322 reads (19%) | catalogued as rs968024150; called by muse, mutect2, varscan2
- PROB1 | c.2892C>A p.P964= | Silent (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- RYR1 | c.3462C>T p.L1154= | Silent (SNP) | VAF 60/280 reads (21%) | called by muse, mutect2, varscan2
- SF3A2 | c.63G>A p.E21= | Silent (SNP) | VAF 53/340 reads (16%) | catalogued as COSV55554910; called by muse, mutect2, varscan2
- SYT13 | c.168C>T p.L56= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as COSV50077201; called by muse, mutect2, varscan2
- ZSWIM9 | c.777C>T p.A259= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- AC005863.1 | n.1544A>C | RNA (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83244G>A | Intron (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ALK | c.3516-142G>A | Intron (SNP) | VAF 62/176 reads (35%) | called by muse, mutect2, varscan2
- ARPIN | c.*1822A>G | 3'UTR (SNP) | VAF 91/259 reads (35%) | called by muse, mutect2, varscan2
- BROX | c.*1910dup | 3'UTR (INS) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- CAMK2A | c.-432C>T | 5'UTR (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- CHEK1 | chr11:125625796 A>G | 5'Flank (SNP) | VAF 75/278 reads (27%) | called by muse, mutect2, varscan2
- CHRDL2 | c.83-84T>A | Intron (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- CLNK | c.*2021G>A | 3'UTR (SNP) | VAF 57/107 reads (53%) | called by muse, mutect2, varscan2
- CTNND2 | c.*237T>A | 3'UTR (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- CTSH | c.*572G>A | 3'UTR (SNP) | VAF 44/257 reads (17%) | catalogued as rs970493820; called by muse, mutect2, varscan2
- CYP11B1 | c.955-27C>G | Intron (SNP) | VAF 87/241 reads (36%) | called by muse, mutect2, varscan2
- DHRS4L1 | n.177-391G>T | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- ENPEP | c.*2167A>T | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- EPPIN | c.391+107C>T | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- FAM114A1 | c.*1731G>C | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- FAM222A | c.*389G>A | 3'UTR (SNP) | VAF 40/105 reads (38%) | catalogued as rs907287436; called by muse, mutect2, varscan2
- FCHO2 | c.940-27_940-25del | Intron (DEL) | VAF 23/79 reads (29%) | catalogued as rs1416276492; called by mutect2, pindel, varscan2
- FGD5 | c.*117G>A | 3'UTR (SNP) | VAF 126/464 reads (27%) | called by muse, mutect2, varscan2
- FOXS1 | c.*180G>A | 3'UTR (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+5151C>T | Intron (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- GADL1 | c.*744T>G | 3'UTR (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- GDF10 | c.*17A>C | 3'UTR (SNP) | VAF 45/112 reads (40%) | catalogued as rs782628358; called by muse, mutect2, varscan2
- GMPPB | c.*1647G>C | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- GNG4 | c.*812C>T | 3'UTR (SNP) | VAF 18/60 reads (30%) | catalogued as rs370257117; called by muse, mutect2, varscan2
- GNG4 | c.*414A>G | 3'UTR (SNP) | VAF 25/88 reads (28%) | catalogued as rs1333889427; called by muse, mutect2, varscan2
- GRIN1 | c.2590-155C>T | Intron (SNP) | VAF 26/89 reads (29%) | catalogued as rs899429798, COSV59297986; called by muse, mutect2, varscan2
- GRM7-AS3 | n.72+4442C>A | Intron (SNP) | VAF 71/199 reads (36%) | called by muse, mutect2
- GRPEL2 | c.*892A>G | 3'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- H4C5 | c.*3C>T | 3'UTR (SNP) | VAF 97/342 reads (28%) | catalogued as rs376175670; called by muse, mutect2, varscan2
- IFIT2 | c.*1028G>C | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- IFNE | c.-203A>T | 5'UTR (SNP) | VAF 27/85 reads (32%) | catalogued as rs1223511514; called by muse, mutect2, varscan2
- IGF2BP1 | c.*4804A>C | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*3487A>G | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- IGFBP6 | c.*159G>T | 3'UTR (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- ITGAM | c.2979+39C>T | Intron (SNP) | VAF 53/122 reads (43%) | called by muse, varscan2
- JPH4 | c.*216C>T | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- KCNC2 | c.*797T>G | 3'UTR (SNP) | VAF 155/392 reads (40%) | called by muse, mutect2, varscan2
- KCNG3 | c.-390G>T | 5'UTR (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- LGALS8 | c.*334T>C | 3'UTR (SNP) | VAF 57/98 reads (58%) | called by muse, mutect2, varscan2
- LRPPRC | c.*704C>T | 3'UTR (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- LURAP1L | c.-405G>A | 5'UTR (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- LYPLA2P2 | n.127C>T | RNA (SNP) | VAF 15/67 reads (22%) | called by mutect2, varscan2
- MARCO | c.*8A>C | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- MARK1 | c.*374G>T | 3'UTR (SNP) | VAF 28/94 reads (30%) | called by muse, varscan2
- MARK4 | c.1877+264G>A | Intron (SNP) | VAF 77/242 reads (32%) | catalogued as rs1433715099, COSV53466825; called by muse, mutect2, varscan2
- MRAS | c.448-22C>T | Intron (SNP) | VAF 52/166 reads (31%) | called by muse, mutect2, varscan2
- MTAP | c.813+7594_813+7595del | Intron (DEL) | VAF 14/32 reads (44%) | catalogued as rs1485152121; called by pindel, varscan2
- NOS1 | c.*6594A>G | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- NSMCE4A | c.988+29G>A | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- OSBPL8 | c.*2322A>G | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as rs902665678; called by muse, mutect2, varscan2
- PHF6 | c.968+2616del | Intron (DEL) | VAF 18/20 reads (90%) | called by mutect2, varscan2
- PHYH | c.*405dup | 3'UTR (INS) | VAF 36/74 reads (49%) | called by mutect2, varscan2
- PLEKHS1 | chr10:113782697 G>T | 3'Flank (SNP) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- PPP1CA | c.523+55G>A | Intron (SNP) | VAF 24/62 reads (39%) | catalogued as rs1240964776; called by muse, mutect2, varscan2
- PTCHD1 | c.*5021G>A | 3'UTR (SNP) | VAF 39/44 reads (89%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5270C>T | Intron (SNP) | VAF 52/190 reads (27%) | catalogued as rs980419506; called by muse, mutect2, varscan2
- PYCR2 | c.*410A>G | 3'UTR (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2, varscan2
- RHO | c.*551G>A | 3'UTR (SNP) | VAF 39/122 reads (32%) | catalogued as rs933661466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RN7SL860P | chr19:22603466 G>A | 3'Flank (SNP) | VAF 73/283 reads (26%) | catalogued as rs934183764; called by muse, mutect2, varscan2
- SAP18 | c.*1392A>C | 3'UTR (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- SAR1B | c.*2942T>C | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- SLC19A2 | c.*1319dup | 3'UTR (INS) | VAF 31/127 reads (24%) | called by mutect2, pindel, varscan2
- SLC24A3 | c.*1394G>T | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- SLC2A13 | c.1034+286C>T | Intron (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- SNORD116-14 | n.69G>A | RNA (SNP) | VAF 109/427 reads (26%) | catalogued as rs373403051; called by muse, mutect2, varscan2
- SPSB3 | c.126+13G>C | Intron (SNP) | VAF 82/190 reads (43%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*2968G>T | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- SV2C | c.*5190G>A | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- SYNCRIP | c.*601C>A | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by mutect2, varscan2
- TEX21P | n.1326C>T | RNA (SNP) | VAF 16/57 reads (28%) | catalogued as rs1243545885; called by muse, mutect2, varscan2
- TMEM250 | c.*622A>G | 3'UTR (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2
- TNFRSF10B | c.748+14G>A | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- TP53I11 | c.*578A>G | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.*345C>T | 3'UTR (SNP) | VAF 53/224 reads (24%) | called by muse, mutect2, varscan2
- UGGT1 | c.*2323C>G | 3'UTR (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- ZFHX3 | c.*1567C>A | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ZNF804B | c.*32T>A | 3'UTR (SNP) | VAF 95/371 reads (26%) | called by muse, mutect2, varscan2
